Somatic mutation profile of tumor specimen TCGA-A2-A0SW-01A (aliquot TCGA-A2-A0SW-01A-11D-A099-09) from TCGA case TCGA-A2-A0SW, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IV; Age at diagnosis: 82.4 years (30,085 days).
Specimen TCGA-A2-A0SW-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 789cf53d-e3ea-4ad0-bd57-d40b8348e5ff.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-A2-A0SW-10A (Blood Derived Normal), aliquot TCGA-A2-A0SW-10A-01W-A097-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ac4e01f0-0ad6-454d-b01a-251c6f33f384

The open-access MAF lists 58 somatic variants for this specimen: 45 protein-altering or splice-affecting, 9 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 39, Silent 9, Splice Site 2, Frame Shift Del 1, Frame Shift Ins 1, Intron 1, 3'Flank 1, In Frame Ins 1, Splice Region 1, 5'Flank 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3R1 | c.1394_1405dup p.E468_E469insGLYE (on ENST00000521381 / NM_181523.3; = p.E198_E199insGLYE on NM_181504.4) | In Frame Ins (INS) | VAF 48/132 reads (36%) | hotspot (GDC flag); catalogued as COSV57129893; called by mutect2, varscan2
- TP53 | c.817C>T p.R273C | Missense Mutation (SNP) | VAF 15/35 reads (43%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121913343, CM010471, CM010473, CM951233, COSV52662066, COSV52670856, COSV52707054, COSV53164203; ClinVar: not provided / uncertain significance / pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCA10 | c.4210G>A p.E1404K | Missense Mutation (SNP) | VAF 22/140 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52225977; called by muse, mutect2, varscan2
- CAPZA2 | c.593A>T p.Y198F | Missense Mutation (SNP) | VAF 44/484 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.75); catalogued as COSV100753977; called by muse, mutect2
- CDH6 | c.1826C>T p.T609M | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.715); catalogued as rs768778721, COSV54073921; called by muse, mutect2, varscan2
- CHRND | c.1429G>T p.V477L | Missense Mutation (SNP) | VAF 3/27 reads (11%) | SIFT tolerated (0.34); PolyPhen benign (0.435); catalogued as COSV99286071; called by muse, mutect2
- CNOT2 | c.420G>T p.M140I | Missense Mutation (SNP) | VAF 15/84 reads (18%) | SIFT tolerated (0.38); PolyPhen benign (0.003); catalogued as COSV57504548; called by muse, mutect2, varscan2
- CSTF2 | c.1032-1G>T p.X344_splice | Splice Site (SNP) | VAF 3/12 reads (25%) | catalogued as COSV100880623, COSV100880854; called by muse, mutect2
- DDX50 | c.202G>A p.E68K | Missense Mutation (SNP) | VAF 19/83 reads (23%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.162); catalogued as COSV65292845; called by muse, mutect2, varscan2
- DKK4 | c.414G>A p.K138= | Splice Region (SNP) | VAF 85/454 reads (19%) | catalogued as COSV55182834; called by muse, mutect2, varscan2
- FAM20A | c.827G>A p.R276Q | Missense Mutation (SNP) | VAF 53/216 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs147371993; called by muse, mutect2, varscan2
- FGA | c.1663A>G p.T555A | Missense Mutation (SNP) | VAF 20/81 reads (25%) | SIFT tolerated (0.08); PolyPhen benign (0.046); catalogued as COSV57398179; called by muse, mutect2, varscan2
- GPRIN3 | c.2095T>A p.S699T | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60885547; called by muse, mutect2, varscan2
- LRBA | c.1432C>G p.P478A | Missense Mutation (SNP) | VAF 61/209 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV63959362; called by muse, mutect2, varscan2
- LRRC8B | c.929A>C p.E310A | Missense Mutation (SNP) | VAF 57/237 reads (24%) | SIFT tolerated (0.29); PolyPhen benign (0.011); catalogued as COSV58376064; called by muse, mutect2, varscan2
- METTL7B | c.497C>A p.P166Q | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.982); catalogued as COSV57697688; called by muse, mutect2, varscan2
- MICU3 | c.757G>A p.D253N | Missense Mutation (SNP) | VAF 70/330 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58847286; called by muse, mutect2, varscan2
- MYO3B | c.1247C>T p.A416V | Missense Mutation (SNP) | VAF 10/195 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100511383; called by muse, mutect2
- NCKAP5 | c.278A>G p.E93G | Missense Mutation (SNP) | VAF 16/61 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.852); catalogued as COSV58458823; called by muse, mutect2, varscan2
- NID2 | c.3276G>C p.M1092I | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT tolerated (0.69); PolyPhen benign (0); catalogued as COSV53499419; called by muse, mutect2, varscan2
- OR13C5 | c.905A>T p.D302V | Missense Mutation (SNP) | VAF 42/448 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.482); catalogued as COSV101053156; called by muse, mutect2
- OR5R1 | c.902C>T p.S301L | Missense Mutation (SNP) | VAF 14/207 reads (7%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100393547; called by muse, mutect2
- PAK5 | c.1183A>C p.I395L | Missense Mutation (SNP) | VAF 16/72 reads (22%) | SIFT tolerated (0.67); PolyPhen benign (0); catalogued as COSV62032310; called by muse, varscan2
- PDE6C | c.2248G>A p.D750N | Missense Mutation (SNP) | VAF 38/161 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65116636; called by muse, mutect2, varscan2
- PLXNA4 | c.2297C>T p.S766F | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as COSV58142243; called by muse, mutect2, varscan2
- PPP4R4 | c.2513T>C p.L838S | Missense Mutation (SNP) | VAF 43/123 reads (35%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.241); catalogued as COSV58556194; called by muse, mutect2, varscan2
- PTPRB | c.5137G>A p.V1713M | Missense Mutation (SNP) | VAF 37/231 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as rs1163632246, COSV54246657; called by muse, mutect2, varscan2
- RACK1 | c.260T>G p.L87R | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65174908; called by muse, mutect2, varscan2
- RPL18A | c.496C>T p.R166C | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as rs1163694896, COSV55830496; called by muse, mutect2, varscan2
- SERPINB12 | c.211C>G p.P71A | Missense Mutation (SNP) | VAF 23/115 reads (20%) | SIFT tolerated (0.05); PolyPhen benign (0.197); catalogued as COSV54034055; called by muse, mutect2, varscan2
- SLC29A4 | c.1162C>T p.P388S | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51875540; called by muse, mutect2
- SRSF11 | c.1441G>A p.D481N | Missense Mutation (SNP) | VAF 22/91 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.307); catalogued as COSV63937387; called by muse, mutect2, varscan2
- STARD4 | c.547C>G p.Q183E | Missense Mutation (SNP) | VAF 34/155 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.616); catalogued as COSV56968475; called by muse, mutect2, varscan2
- SUCLA2 | c.1106T>G p.V369G (on ENST00000643023; = p.V348G on NM_003850.3) | Missense Mutation (SNP) | VAF 22/58 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.519); catalogued as rs1282208356, COSV66222499; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SVIL | c.5530-1G>A p.X1844_splice (on ENST00000355867 / NM_021738.3; = p.X1418_splice on NM_003174.3 and 1 other RefSeq transcript) | Splice Site (SNP) | VAF 22/78 reads (28%) | catalogued as COSV100881468; called by muse, mutect2, varscan2
- TCHH | c.202C>T p.R68C | Missense Mutation (SNP) | VAF 46/84 reads (55%) | SIFT tolerated, low confidence (0.07); PolyPhen probably damaging (0.961); catalogued as COSV64274704; called by muse, mutect2, varscan2
- USH2A | c.13144C>A p.Q4382K | Missense Mutation (SNP) | VAF 3/24 reads (13%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as COSV100240371; called by muse, mutect2
- USP15 | c.2426G>A p.C809Y (on ENST00000280377 / NM_001351159.2; = p.C780Y on NM_006313.3 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 43/248 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54795232; called by muse, mutect2, varscan2
- XRCC1 | c.70C>T p.L24F | Missense Mutation (SNP) | VAF 18/56 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53451140; called by muse, mutect2, varscan2
- ZNF107 | c.1544A>G p.K515R | Missense Mutation (SNP) | VAF 20/98 reads (20%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.581); catalogued as COSV61330122; called by muse, mutect2, varscan2
- ZNF160 | c.2363G>A p.R788H | Missense Mutation (SNP) | VAF 35/140 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.012); catalogued as rs187006418, COSV62000286; called by muse, mutect2, varscan2
- ZNF251 | c.793T>C p.F265L | Missense Mutation (SNP) | VAF 22/98 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.684); catalogued as COSV99478767; called by muse, mutect2, varscan2
- ZNF280C | c.1403G>C p.G468A | Missense Mutation (SNP) | VAF 24/174 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100921261; called by muse, mutect2, varscan2
- MERTK | c.2051_2069del p.L684Qfs*12 | Frame Shift Del (DEL) | VAF 42/257 reads (16%) | called by mutect2, pindel, varscan2
- ZC3H6 | c.2176dup p.T726Nfs*17 | Frame Shift Ins (INS) | VAF 25/100 reads (25%) | called by mutect2, pindel, varscan2
- ABCB1 | c.1812A>G p.G604= | Silent (SNP) | VAF 17/107 reads (16%) | catalogued as COSV55956364; called by muse, mutect2, varscan2
- CSMD1 | c.8643C>T p.V2881= (on ENST00000520002; = p.V2880= on NM_033225.6) | Silent (SNP) | VAF 4/20 reads (20%) | catalogued as rs368382333; called by muse, mutect2, varscan2
- FRG2C | c.540G>C p.V180= | Silent (SNP) | VAF 19/229 reads (8%) | called by muse, mutect2
- GTF2IRD2B | c.378A>G p.T126= | Silent (SNP) | VAF 12/44 reads (27%) | catalogued as rs1272109637, COSV57031668; called by muse, mutect2, varscan2
- HTRA3 | c.925C>T p.L309= | Silent (SNP) | VAF 17/71 reads (24%) | catalogued as COSV56471970; called by muse, mutect2, varscan2
- HTT | c.1200C>T p.G400= | Silent (SNP) | VAF 11/48 reads (23%) | catalogued as COSV100751128; called by muse, mutect2, varscan2
- MYRF | c.2298G>A p.Q766= (on ENST00000278836 / NM_001127392.3; = p.Q757= on NM_013279.4) | Silent (SNP) | VAF 13/57 reads (23%) | catalogued as rs1447311454, COSV53891256; called by muse, mutect2, varscan2
- RNF2 | c.133C>T p.L45= | Silent (SNP) | VAF 116/203 reads (57%) | catalogued as COSV62279838; called by muse, mutect2, varscan2
- XPOT | c.132G>A p.Q44= | Silent (SNP) | VAF 48/324 reads (15%) | catalogued as COSV60346689; called by muse, mutect2, varscan2
- COPS9 | chr2:240126674 ins A | 3'Flank (INS) | VAF 55/235 reads (23%) | called by mutect2, pindel, varscan2
- HMGB1P1 | n.619G>C | RNA (SNP) | VAF 140/419 reads (33%) | called by muse, mutect2, varscan2
- RTBDN | chr19:12834806 T>C | 5'Flank (SNP) | VAF 12/30 reads (40%) | catalogued as COSV52250335; called by muse, mutect2, varscan2
- TTN | c.10360+2944A>G | Intron (SNP) | VAF 35/162 reads (22%) | catalogued as COSV60184040; called by muse, mutect2, varscan2
